Gene-level copy-number profile of tumor specimen TCGA-HE-7130-01A from TCGA case TCGA-HE-7130, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III.
Specimen TCGA-HE-7130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.2518018f-8f41-4203-82dd-9b20bfaf6771.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HE-7130-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5b52d04-aba5-4f69-88f6-b1e29bc99de7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 11; copy number 2: 10,303; copy number 3: 15,307; copy number 4: 20,980; copy number 5: 7,410; copy number 6: 2,680; copy number 7: 1,078; copy number 8: 1,684; copy number 9: 163; copy number 10: 45; copy number 14: 23; copy number 21: 79.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HE-7130-01A-11D-1959-01): tumor purity 0.77, ploidy 3.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,532,552–22,029,594, 53 genes (within-gene range 0–2): AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr18:2,778,941–2,779,057, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 310 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,069,168–3,438,621, 1 gene, copy number 9 (within-gene range 7–9): PRDM16.
- chr1:3,205,988–4,019,508, 29 genes, copy number 9: AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1, CEP104, DFFB, C1orf174, LINC01134, LINC01346, LINC01345, LINC02780, AL805961.1.
- chr1:6,785,454–7,769,706, 1 gene, copy number 9 (within-gene range 7–10): CAMTA1.
- chr1:7,219,360–9,088,478, 49 genes, copy number 9–10 (within-gene range 7–10): RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1, AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5.
- chr1:13,474,973–13,825,079, 8 genes, copy number 9 (within-gene range 7–9): LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr1:15,465,909–17,401,699, 99 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:169,104,124–169,854,080, 15 genes, copy number 9 (within-gene range 6–9): AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181, SLC19A2, AL021068.1, Z99572.1, F5, SELP, C1orf112, SELL, SELE, AL021940.1.
- chr3:171,534,423–171,996,871, 6 genes, copy number 9: AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1.
- chr11:67,538,899–70,436,584, 101 genes, copy number 14–21 (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 14: AP001271.1.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
